Somatic mutation profile of tumor specimen HCM-CSHL-0191-C25-01A (aliquot HCM-CSHL-0191-C25-01A-11D-A78L-36) from HCMI case HCM-CSHL-0191-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 75.5 years (27,561 days).
Specimen HCM-CSHL-0191-C25-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41c9a5b6-8f32-4e1c-bbb1-ae9dd5aa3943.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0191-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0191-C25-10A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31bdc9b5-d0cc-4b51-a15c-8282e6b6ba4e

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 3, Intron 2, 3'Flank 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.645T>A p.S215R | Missense Mutation (SNP) | VAF 20/372 reads (5%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD941799, COSV52752255, COSV52783847, COSV52798196; called by muse, mutect2
- CTDSP2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs767635273; called by muse, mutect2
- FAM189A1 | c.1230C>T p.G410= | Splice Region (SNP) | VAF 10/280 reads (4%) | catalogued as rs1318028148, COSV54268486; called by muse, mutect2
- NFKBIL1 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.892); catalogued as rs769052971; called by muse, mutect2
- SEMA6C | c.2336C>T p.P779L | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.035); catalogued as rs1473303306; called by muse, mutect2
- ZDBF2 | c.1856C>T p.P619L | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.145); catalogued as COSV65630257; called by muse, mutect2
- CDCA7 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSF1R | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 24/686 reads (3%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2
- KIT | c.164G>T p.R55M | Missense Mutation (SNP) | VAF 9/225 reads (4%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.659); called by muse, mutect2
- LDB2 | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 23/554 reads (4%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2
- LPCAT2 | c.1333G>A p.D445N | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MIB2 | c.475A>T p.S159C | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TDRD15 | c.1219A>G p.T407A | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.78); PolyPhen benign (0.001); called by muse, mutect2
- ACAN | c.1947C>T p.G649= | Silent (SNP) | VAF 17/293 reads (6%) | catalogued as rs377391149; called by muse, mutect2
- GABRA1 | c.396G>A p.K132= | Silent (SNP) | VAF 15/445 reads (3%) | catalogued as COSV50099491, COSV50101391; called by muse, mutect2
- PCDHB16 | c.1965C>T p.T655= | Silent (SNP) | VAF 61/845 reads (7%) | catalogued as rs782521205; called by muse, mutect2
- MUC19 | chr12:40546411 C>A | 3'Flank (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- OPA1 | c.2983+1201C>T | Intron (SNP) | VAF 20/584 reads (3%) | called by muse, mutect2
- PTPN6 | c.8+19C>T | Intron (SNP) | VAF 29/418 reads (7%) | catalogued as rs782087979; called by muse, mutect2
